Somatic mutation profile of tumor specimen C3N-01518-01 (aliquot CPT0167640006) from CPTAC case C3N-01518, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.0 years (26,312 days).
Specimen C3N-01518-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d58a020-b843-41c2-a6d5-4afae2a83070.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01518-71 (Blood Derived Normal), aliquot CPT0167700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec7aa477-e576-4e60-ace1-047db27ee28d

The open-access MAF lists 87 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Nonsense Mutation 7, Intron 6, RNA 3, Splice Site 2, Splice Region 2, IGR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM161A | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 98/256 reads (38%) | catalogued as rs267606794, CM105647, COSV56765545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 112/355 reads (32%) | catalogued as rs1555614261, COSV62206646; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 73/132 reads (55%) | catalogued as rs121913301, CM951105, CM961226, COSV57296833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 357/548 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AC126283.2 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 91/332 reads (27%) | catalogued as rs121964913, CM041379, COSV67100279; ClinVar: risk factor; called by muse, mutect2, varscan2
- ATG2B | c.5261G>A p.R1754K | Missense Mutation (SNP) | VAF 13/369 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1227515102, COSV55889435; called by muse, mutect2
- AXIN1 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 33/350 reads (9%) | catalogued as COSV51994551; called by muse, mutect2
- CD5L | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 31/485 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs769560475; called by muse, mutect2
- CNTNAP3 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 123/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1322493756; called by muse, mutect2, varscan2
- COL1A2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 167/794 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.89); catalogued as rs774774401, COSV99800686; called by muse, mutect2, varscan2
- FRAS1 | c.10768T>A p.S3590T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1402972207; called by muse, mutect2
- GCC1 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 110/474 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100365691; called by muse, mutect2, varscan2
- GNAS | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1262494456, COSV100006523; called by muse, mutect2, varscan2
- GUCA1B | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 172/555 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478636152; called by muse, mutect2, varscan2
- HPGDS | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148462970; called by muse, mutect2, varscan2
- MAN2C1 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV51226672; called by muse, mutect2
- MFAP3L | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs142955967; called by muse, mutect2, varscan2
- OR2M7 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 113/376 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs183000679, COSV100522619, COSV58738570; called by mutect2, varscan2
- PADI1 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs770352294; called by muse, mutect2, varscan2
- PAX7 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as rs199662942; called by muse, mutect2, varscan2
- PCSK6 | c.1414+4C>T | Splice Region (SNP) | VAF 51/133 reads (38%) | catalogued as rs759132102, COSV59341898; called by muse, mutect2, varscan2
- PDE6B | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs755871033, COSV99728739; called by muse, mutect2, varscan2
- PLCZ1 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776341320; called by muse, mutect2, varscan2
- PTEN | c.644T>C p.F215S | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV64289103; called by muse, mutect2, varscan2
- RASSF8 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs140885233; called by muse, mutect2, varscan2
- SLFN14 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 187/306 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1163391239, COSV101334657; called by muse, mutect2, varscan2
- SPESP1 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 37/202 reads (18%) | catalogued as rs767127121; called by muse, mutect2, varscan2
- TTC31 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs774031823; called by muse, varscan2
- UGT2B11 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749630839; called by muse, mutect2, varscan2
- ZFYVE26 | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs367911364; called by muse, mutect2
- ZNF71 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs769543206; called by muse, mutect2, varscan2
- ARHGAP10 | c.1531G>T p.D511Y | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ASCL4 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 9/290 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2
- CCDC146 | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 136/245 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD53 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- COL16A1 | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CREBBP | c.4729-1G>A p.X1577_splice | Splice Site (SNP) | VAF 25/756 reads (3%) | called by muse, mutect2
- FAM102A | c.745T>G p.S249A (on ENST00000373095 / NM_001035254.3; = p.S107A on NM_203305.2) | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- FERMT3 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GSTP1 | c.-2C>G | Splice Region (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- HCN1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 191/558 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELQ | c.2296-1G>A p.X766_splice | Splice Site (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2
- HNRNPCL2 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-66 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KLF5 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- NEURL3 | c.260G>C p.C87S | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- NLRP13 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 95/529 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NRG3 | c.1872G>C p.W624C (on ENST00000404547 / NM_001370084.1; = p.W600C on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- NWD1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2D3 | c.2del p.M1? | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- OR51F1 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLK5 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PXMP2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RYR3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAXO1 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TAF12 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM210 | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- TNFRSF21 | c.997A>T p.R333W | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOMM70 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRRAP | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- VTCN1 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- ACOXL | c.765G>A p.T255= | Silent (SNP) | VAF 18/182 reads (10%) | catalogued as rs748062919; called by muse, mutect2, varscan2
- ADAR | c.3228G>A p.L1076= | Silent (SNP) | VAF 126/394 reads (32%) | called by muse, mutect2, varscan2
- CRB2 | c.618C>T p.F206= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs1044320885; called by muse, mutect2, varscan2
- EPHA5 | c.1797C>T p.C599= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs781591015, COSV99901552; called by muse, mutect2, varscan2
- GLB1L3 | c.1299G>A p.S433= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs376258309; called by muse, mutect2, varscan2
- GRIN3A | c.282C>T p.G94= | Silent (SNP) | VAF 14/167 reads (8%) | catalogued as rs770944736, COSV62451516; called by muse, mutect2
- KCNC2 | c.582C>T p.D194= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as rs768447661, COSV54363256; called by muse, mutect2, varscan2
- NTSR1 | c.837C>T p.V279= | Silent (SNP) | VAF 95/255 reads (37%) | catalogued as rs775960298; called by muse, mutect2, varscan2
- RYR2 | c.9189C>T p.N3063= | Silent (SNP) | VAF 96/249 reads (39%) | catalogued as rs531651646, COSV63685011; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHANK1 | c.1707C>T p.A569= | Silent (SNP) | VAF 74/207 reads (36%) | catalogued as rs1054681436, COSV53260169; called by muse, mutect2, varscan2
- SLC25A44 | c.498C>G p.T166= | Silent (SNP) | VAF 17/385 reads (4%) | called by muse, mutect2
- SPEM2 | c.696C>T p.P232= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as rs1476531849; called by muse, mutect2
- UTRN | c.3723T>C p.Y1241= | Silent (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- ZNF558 | c.36G>A p.P12= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as rs140932208; called by muse, mutect2, varscan2
- C3P1 | n.3402C>T | RNA (SNP) | VAF 173/579 reads (30%) | called by muse, mutect2, varscan2
- CASR | c.1378-6142G>A | Intron (SNP) | VAF 208/587 reads (35%) | catalogued as rs866241407, COSV56138761; called by muse, mutect2, varscan2
- IKZF1 | c.161-8347C>T | Intron (SNP) | VAF 110/387 reads (28%) | catalogued as rs267601536, COSV58793065; called by muse, mutect2, varscan2
- KIFC3 | c.*188C>T | 3'UTR (SNP) | VAF 204/626 reads (33%) | catalogued as rs566453178; called by muse, mutect2, varscan2
- MIR193A | n.32G>T | RNA (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- OS9 | c.163-17C>A | Intron (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- PCDHGA1 | c.2421+20_2421+21del | Intron (DEL) | VAF 45/159 reads (28%) | called by mutect2, pindel, varscan2
- PKHD1 | c.10156+22424C>A | Intron (SNP) | VAF 71/220 reads (32%) | called by muse, mutect2, varscan2
- RGSL1 | c.301+516T>C | Intron (SNP) | VAF 103/239 reads (43%) | called by muse, mutect2, varscan2
- SKP1P2 | n.326A>G | RNA (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- Unknown | chr2:111238087 C>T | IGR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
